Somatic mutation profile of tumor specimen C3L-02210-01 (aliquot CPT0389570006) from CPTAC case C3L-02210, project CPTAC-3 (Kidney — Complex Mixed and Stromal Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Benign cystic nephroma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 66.3 years (24,212 days).
Specimen C3L-02210-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a27fff8-5924-478c-bd21-1ba29c01e753.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02210-31 (Blood Derived Normal), aliquot CPT0389630002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51f83310-8df6-4838-b717-09aa773386d1

The open-access MAF lists 9 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, 5'UTR 2, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP52 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs139653833; called by muse, mutect2, varscan2
- GLI3 | c.1075A>G p.M359V | Missense Mutation (SNP) | VAF 108/569 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRPS22 | c.431A>G p.D144G (on ENST00000310776 / NM_001363893.1; = p.D145G on NM_020191.4) | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- AASDH | c.486T>C p.Y162= | Silent (SNP) | VAF 48/192 reads (25%) | catalogued as rs750549283, COSV99221714; called by muse, mutect2, varscan2
- ARF5 | c.-43C>T | 5'UTR (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- CAMK2A | c.1033+141T>C | Intron (SNP) | VAF 49/226 reads (22%) | called by muse, mutect2, varscan2
- TSSK4 | c.441-207A>G | Intron (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- TTC3P1 | n.5349G>A | RNA (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- UBE2C | c.-3C>A | 5'UTR (SNP) | VAF 15/483 reads (3%) | catalogued as rs995344489; called by muse, mutect2
